Somatic mutation profile of tumor specimen TCGA-DD-A39V-01A (aliquot TCGA-DD-A39V-01A-11D-A20W-10) from TCGA case TCGA-DD-A39V, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 77.4 years (28,254 days).
Specimen TCGA-DD-A39V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1565fde9-53ec-41b4-9d64-82cd9a410d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A39V-11A (Solid Tissue Normal), aliquot TCGA-DD-A39V-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12c82f4a-07cf-488d-967d-22ef748e0a43

The open-access MAF lists 77 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Nonsense Mutation 6, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 71/224 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 49/115 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- ABCA10 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as rs200246933, COSV52220026; called by muse, mutect2, varscan2
- ADAMTS19 | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV50733816, COSV50751508; called by muse, mutect2, varscan2
- ANKZF1 | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV60133365; called by muse, mutect2, varscan2
- ARHGAP39 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52768468, COSV52770832; called by muse, mutect2, varscan2
- ATXN7L3 | c.543T>A p.D181E (on ENST00000389384 / NM_001382309.1; = p.D188E on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV60228919; called by muse, mutect2, varscan2
- BFSP2 | c.974C>A p.S325* | Nonsense Mutation (SNP) | VAF 19/180 reads (11%) | catalogued as rs751496741, COSV56587692, COSV56589120; called by muse, mutect2, varscan2
- BIRC7 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV53901468; called by muse, mutect2, varscan2
- BRCA1 | c.5303G>A p.C1768Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs730881497, COSV58790970; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- C1orf43 | c.530T>C p.L177P (on ENST00000368521 / NM_001297718.2; = p.L143P on NM_015449.4) | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV62966354; called by muse, mutect2, varscan2
- CFAP92 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as rs765406321, COSV54047583; called by muse, mutect2, varscan2
- CNTNAP5 | c.2419T>A p.F807I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV70488409; called by muse, mutect2
- COMMD3-BMI1 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV64959164; called by muse, mutect2, varscan2
- DHCR24 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as rs1218323792, COSV64874767; called by muse, mutect2, varscan2
- DHX33 | c.647G>T p.R216M | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV56579255; called by muse, mutect2, varscan2
- DST | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs183558657, COSV56808337; called by muse, mutect2, varscan2
- DUOXA1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50993756; called by muse, mutect2, varscan2
- EPX | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs1439178803, COSV56596643; called by muse, mutect2
- FBXL16 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV60964641; called by muse, mutect2, varscan2
- FMO2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.786); catalogued as COSV52947983; called by muse, mutect2, varscan2
- FNIP2 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV52440575; called by muse, mutect2, varscan2
- FOCAD | c.3020T>A p.L1007* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV58100159; called by muse, mutect2, varscan2
- GMIP | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.152); catalogued as rs948233674, COSV52556646; called by muse, mutect2, varscan2
- HECW1 | c.1502A>G p.E501G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as COSV67830795; called by muse, mutect2
- HJURP | c.1916T>G p.L639W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64978871; called by muse, mutect2, varscan2
- HTR3E | c.319T>A p.C107S (on ENST00000415389 / NM_001256613.1; = p.C122S on NM_182589.2) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58947082; called by muse, mutect2, varscan2
- LCA5 | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63971587; called by muse, varscan2
- MOXD1 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60944919; called by muse, mutect2
- MYO10 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs192053260; called by muse, mutect2, varscan2
- NOL4 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1267178451, COSV52348516; called by muse, mutect2, varscan2
- NOS1 | c.4028C>A p.A1343D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); catalogued as COSV100500075, COSV57609591; called by muse, mutect2, varscan2
- PAX3 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs987480491, COSV60588734; called by muse, mutect2, varscan2
- PDF | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54750886; called by muse, mutect2, varscan2
- PMVK | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as rs1487418854, COSV63785905; called by muse, mutect2, varscan2
- PROM1 | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as CM083044, COSV101477144, COSV71699500; called by muse, mutect2, varscan2
- PTTG2 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 53/152 reads (35%) | catalogued as COSV54719834; called by muse, mutect2, varscan2
- QTRT1 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51550749, COSV51551559; called by muse, mutect2, varscan2
- SBF1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62367899; called by muse, mutect2, varscan2
- SEMA3D | c.2252A>C p.K751T | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV52394631; called by muse, mutect2, varscan2
- SLC26A11 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV63279730; called by muse, mutect2, varscan2
- ST18 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52495510; called by muse, mutect2, varscan2
- SYNE2 | c.6904C>T p.Q2302* | Nonsense Mutation (SNP) | VAF 79/238 reads (33%) | catalogued as COSV59952542; called by muse, mutect2, varscan2
- THEG | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.015); catalogued as rs1190840382, COSV61073945, COSV61074467; called by muse, mutect2, varscan2
- TIAM2 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV59695159; called by muse, mutect2, varscan2
- WASF3 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV58966605; called by muse, mutect2, varscan2
- WDR81 | c.3860T>C p.L1287P (on ENST00000409644 / NM_001163809.2; = p.L236P on NM_152348.4) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV58483419; called by muse, mutect2, varscan2
- XKR7 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1294070844, COSV101629233; called by muse, mutect2
- ZC3H6 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV59668039; called by muse, mutect2, varscan2
- ZNF577 | c.1433A>C p.Y478S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV56816156; called by muse, mutect2, varscan2
- ZNF770 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62544366; called by muse, mutect2, varscan2
- ZNRF3 | c.446G>C p.R149P (on ENST00000544604 / NM_001206998.2; = p.R49P on NM_032173.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60432046, COSV60434741; called by muse, mutect2, varscan2
- ARID1A | c.5195dup p.E1733Gfs*3 | Frame Shift Ins (INS) | VAF 48/106 reads (45%) | called by mutect2, pindel, varscan2
- CDH18 | c.152_161del p.P51Hfs*10 | Frame Shift Del (DEL) | VAF 55/132 reads (42%) | called by mutect2, pindel, varscan2
- PCSK1 | c.1658del p.F553Sfs*12 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | called by mutect2, pindel, varscan2
- SPTA1 | c.412del p.H138Tfs*7 | Frame Shift Del (DEL) | VAF 61/221 reads (28%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1899A>G p.A633= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV65397942; called by muse, mutect2, varscan2
- CDHR2 | c.2475C>T p.H825= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as rs180931810; called by muse, mutect2, varscan2
- DGKQ | c.159G>T p.P53= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV56617727; called by muse, mutect2, varscan2
- DIS3L | c.582T>A p.P194= (on ENST00000319212 / NM_001143688.3; = p.P111= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1005946073, COSV59912511; called by muse, mutect2, varscan2
- GLDC | c.1425A>G p.T475= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV58680583; called by muse, mutect2, varscan2
- HAVCR1 | c.420C>T p.T140= | Silent (SNP) | VAF 28/344 reads (8%) | catalogued as rs566987531, COSV100208459, COSV59398378, COSV59400159; called by muse, mutect2
- HOXC9 | c.72A>G p.L24= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV57716787; called by muse, mutect2, varscan2
- KDM5B | c.3336G>A p.L1112= | Silent (SNP) | VAF 65/364 reads (18%) | catalogued as COSV52508357; called by muse, mutect2, varscan2
- MAP4K3 | c.1086A>G p.S362= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55713623; called by muse, mutect2, varscan2
- MRC2 | c.3757C>A p.R1253= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as COSV57640236; called by muse, mutect2, varscan2
- NOS1 | c.4029C>A p.A1343= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100500073; called by muse, mutect2, varscan2
- PCDHA6 | c.1389C>T p.F463= | Silent (SNP) | VAF 34/373 reads (9%) | catalogued as rs781847846, COSV65343220; called by muse, mutect2
- TTC29 | c.435T>A p.A145= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV57275955; called by muse, mutect2, varscan2
- TULP1 | c.1266C>T p.T422= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs747534563, COSV57692726; called by muse, mutect2, varscan2
- ZFAND5 | c.597A>G p.R199= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs769951584, COSV52988737; called by muse, mutect2, varscan2
- ZNF77 | c.918C>T p.S306= | Silent (SNP) | VAF 76/147 reads (52%) | catalogued as COSV58821960; called by muse, mutect2, varscan2
- ELMOD3 | c.943+129A>C | Intron (SNP) | VAF 15/232 reads (6%) | catalogued as COSV55707542; called by muse, mutect2
- FGFR3 | c.*1381G>A | 3'UTR (SNP) | VAF 41/120 reads (34%) | catalogued as COSV53402633; called by muse, mutect2, varscan2
- IKBIP | c.297+7555del | Intron (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- OSTCP1 | n.493T>C | RNA (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- SWI5 | c.-35C>T | 5'UTR (SNP) | VAF 26/74 reads (35%) | catalogued as rs978957695, COSV60792190; called by muse, mutect2, varscan2
